Somatic mutation profile of tumor specimen ALCH-AET9-TTP1-A (aliquot ALCH-AET9-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AET9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Pleomorphic carcinoma; Age at diagnosis: 58.9 years (21,524 days).
Specimen ALCH-AET9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acd61139-dc0f-45d7-bd71-344a0e1bb35d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AET9-NB1-A (Blood Derived Normal), aliquot ALCH-AET9-NB1-A-2-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb7cb7c0-8087-4efc-a377-477ade0f8252

The open-access MAF lists 1,429 somatic variants for this specimen: 967 protein-altering or splice-affecting, 270 silent, 192 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 811, Silent 270, Intron 95, Nonsense Mutation 67, Splice Site 30, Frame Shift Del 28, RNA 28, 3'UTR 24, 5'UTR 18, Splice Region 17, 5'Flank 16, 3'Flank 11.

Variants (750 of 1,429; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5428G>T p.D1810Y | Missense Mutation (SNP) | VAF 87/696 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 39/157 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 41/176 reads (23%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABHD8 | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV99917088; called by muse, mutect2, varscan2
- AC013489.1 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51553810; called by muse, mutect2, varscan2
- AC100868.1 | c.1858C>A p.Q620K | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.614); catalogued as rs1237542709; called by muse, mutect2, varscan2
- ACSM1 | c.394A>T p.M132L | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1255537924; called by muse, mutect2, varscan2
- ACTRT1 | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV64419836; called by muse, mutect2, varscan2
- ADCY8 | c.2375C>G p.S792C | Missense Mutation (SNP) | VAF 54/445 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV53898884; called by muse, mutect2, varscan2
- ADRA2A | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54529039; called by muse, mutect2, varscan2
- AL121899.2 | c.816C>A p.S272R | Missense Mutation (SNP) | VAF 49/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200572388; called by muse, mutect2, varscan2
- AMD1 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 66/521 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV64387596; called by muse, mutect2, varscan2
- ANK3 | c.10738C>A p.P3580T | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99783008; called by muse, mutect2, varscan2
- ANO2 | c.2543T>C p.L848P (on ENST00000356134 / NM_001278597.3; = p.L852P on NM_001278596.3) | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59032612; called by muse, mutect2, varscan2
- AP1B1 | c.2439G>A p.Q813= | Splice Region (SNP) | VAF 35/312 reads (11%) | catalogued as COSV100434728, COSV58017629; called by muse, mutect2, varscan2
- APC | c.3935G>T p.G1312V | Missense Mutation (SNP) | VAF 114/856 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57331679, COSV57403281; called by muse, varscan2
- ARAF | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.11); catalogued as COSV51692490; called by muse, mutect2, varscan2
- ARHGAP28 | c.1905+1G>T p.X635_splice (on ENST00000383472 / NM_001366230.1; = p.X476_splice on NM_001010000.3) | Splice Site (SNP) | VAF 60/411 reads (15%) | catalogued as COSV51636952, COSV51649229; called by muse, mutect2, varscan2
- ARHGAP36 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 72/527 reads (14%) | catalogued as COSV52272519; called by muse, mutect2, varscan2
- ARID1A | c.4096C>T p.Q1366* | Nonsense Mutation (SNP) | VAF 24/208 reads (12%) | catalogued as COSV61375213; called by muse, mutect2, varscan2
- ASPM | c.7185C>A p.F2395L | Missense Mutation (SNP) | VAF 93/380 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV99659271; called by muse, mutect2, varscan2
- ATP10D | c.3747G>T p.K1249N | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV56707122; called by muse, mutect2, varscan2
- ATP9B | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.084); catalogued as rs1356222387; called by muse, mutect2, varscan2
- B4GALNT2 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55925515; called by muse, mutect2, varscan2
- B4GALNT2 | c.1351C>A p.H451N | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55925795; called by muse, mutect2, varscan2
- BACH2 | c.2318G>T p.G773V | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV99997732; called by muse, mutect2, varscan2
- BCHE | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV100012567; called by muse, mutect2, varscan2
- BCL11A | c.1522G>T p.A508S (on ENST00000335712 / NM_001365609.1; = p.A542S on NM_018014.4) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1239160421, COSV59627719; called by muse, mutect2, varscan2
- BNC2 | c.1789A>G p.T597A | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1563782375; called by muse, mutect2, varscan2
- BOD1L1 | c.4603G>T p.A1535S | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs763986375; called by muse, mutect2, varscan2
- BRCA2 | c.8918G>A p.R2973H | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359143, COSV66461060; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.1480G>C p.G494R (on ENST00000254900 / NM_139199.2; = p.G567R on NM_006696.4) | Missense Mutation (SNP) | VAF 55/464 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV50174243; called by muse, mutect2, varscan2
- C10orf88 | c.460A>G p.R154G | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV64403573; called by muse, mutect2, varscan2
- C8orf74 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58753595, COSV58755560; called by muse, mutect2, varscan2
- CACNA1H | c.1781C>G p.A594G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1290847155; called by mutect2, varscan2
- CAPN3 | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 78/620 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV100533461; called by muse, varscan2
- CAPN3 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 78/616 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.186); catalogued as COSV100533465; called by muse, varscan2
- CARD11 | c.2605C>A p.R869= | Splice Region (SNP) | VAF 17/125 reads (14%) | catalogued as COSV62757724; called by muse, mutect2, varscan2
- CATSPER4 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs201122868; called by muse, mutect2, varscan2
- CBX6 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs957743505; called by muse, varscan2
- CCBE1 | c.546T>A p.N182K | Missense Mutation (SNP) | VAF 59/614 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs1250702775; called by muse, mutect2, varscan2
- CCDC170 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53338207; called by muse, mutect2, varscan2
- CCDC88B | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1321550221; called by muse, mutect2, varscan2
- CCKBR | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV58100360; called by muse, mutect2, varscan2
- CCP110 | c.1094C>G p.P365R | Missense Mutation (SNP) | VAF 46/435 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66816829; called by muse, mutect2, varscan2
- CDADC1 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 57/402 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51913740; called by muse, mutect2, varscan2
- CDH13 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs771613971, COSV51823582, COSV99231844; called by muse, mutect2, varscan2
- CDK13 | c.1514G>T p.S505I | Missense Mutation (SNP) | VAF 71/538 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs778059575; called by muse, mutect2, varscan2
- CEP170 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60506601; called by muse, mutect2, varscan2
- CHAT | c.2053C>G p.Q685E | Missense Mutation (SNP) | VAF 71/456 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV60333640; called by muse, mutect2, varscan2
- CHRDL2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV55222344; called by muse, mutect2, varscan2
- CLASP2 | c.1973G>T p.R658L | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100224461; called by muse, mutect2, varscan2
- CNMD | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs771377682; called by muse, mutect2, varscan2
- CNTN2 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs549298351; called by muse, mutect2, varscan2
- COL15A1 | c.3158G>T p.G1053V | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66651203; called by muse, mutect2, varscan2
- CPA3 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV56047224; called by muse, mutect2, varscan2
- CPA3 | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56047178; called by muse, mutect2, varscan2
- CPNE5 | c.1431+1G>T p.X477_splice | Splice Site (SNP) | VAF 16/101 reads (16%) | catalogued as COSV55196479; called by muse, mutect2, varscan2
- CSMD3 | c.11072G>T p.G3691V (on ENST00000297405 / NM_001363185.1; = p.G3522V on NM_052900.3) | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as COSV52154527; called by muse, mutect2, varscan2
- CSMD3 | c.10681G>T p.V3561L (on ENST00000297405 / NM_001363185.1; = p.V3392L on NM_052900.3) | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52145425; called by muse, mutect2, varscan2
- CSTF3 | c.261A>G p.L87= | Splice Region (SNP) | VAF 36/190 reads (19%) | catalogued as rs923477483; called by muse, mutect2, varscan2
- CTNNA2 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 96/644 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV63565176, COSV63573771; called by muse, mutect2, varscan2
- CTTN | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57230385, COSV57231742, COSV57234480; called by muse, mutect2, varscan2
- CUBN | c.7773G>T p.R2591S | Missense Mutation (SNP) | VAF 190/894 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64713293; called by muse, mutect2, varscan2
- CUBN | c.3603C>A p.S1201R | Missense Mutation (SNP) | VAF 98/731 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64716873; called by muse, mutect2, varscan2
- DCDC1 | c.4555G>T p.D1519Y (on ENST00000597505 / NM_001367979.1; = p.D626Y on NM_020869.3) | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV104410468; called by muse, mutect2, varscan2
- DCLRE1B | c.1142G>T p.W381L | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV65813585; called by muse, mutect2, varscan2
- DDX31 | c.2140+1G>T p.X714_splice | Splice Site (SNP) | VAF 17/120 reads (14%) | catalogued as rs766785080; called by muse, mutect2, varscan2
- DGAT2L6 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 76/572 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV60718531; called by muse, mutect2, varscan2
- DGCR8 | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV61226014; called by muse, mutect2, varscan2
- DGKK | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101053173; called by muse, mutect2, varscan2
- DHRS4L2 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 44/411 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760857123; called by muse, mutect2, varscan2
- DHX9 | c.3277T>C p.S1093P | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs773381253; called by muse, mutect2, varscan2
- DICER1 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 63/483 reads (13%) | catalogued as COSV100601718; called by muse, mutect2, varscan2
- DNAH17 | c.3533C>A p.T1178N | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs776624187; called by muse, mutect2, varscan2
- DNAH7 | c.5393G>A p.R1798K | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV56796100; called by muse, mutect2, varscan2
- DNMT3A | c.2146G>T p.V716F | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1418039680, COSV53040952, COSV99262312; called by muse, mutect2, varscan2
- DOCK2 | c.5060G>T p.G1687V | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99915657; called by muse, mutect2
- DPF3 | c.1082A>G p.H361R | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1465304290; called by muse, mutect2, varscan2
- DPP6 | c.906C>G p.I302M (on ENST00000377770 / NM_001364500.2; = p.I240M on NM_001936.5) | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100127386; called by muse, mutect2, varscan2
- DSC1 | c.954C>A p.Y318* | Nonsense Mutation (SNP) | VAF 32/206 reads (16%) | catalogued as rs1246576868; called by muse, mutect2, varscan2
- DST | c.20590G>C p.E6864Q (on ENST00000361203 / NM_001374722.1; = p.E4561Q on NM_015548.5) | Missense Mutation (SNP) | VAF 39/290 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99757397; called by muse, mutect2, varscan2
- DVL1 | c.1763G>T p.R588L (on ENST00000378888 / NM_001330311.2; = p.R563L on NM_004421.3) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs375813716; called by muse, mutect2, varscan2
- DYNC2H1 | c.7954C>G p.L2652V | Missense Mutation (SNP) | VAF 50/355 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV62087700, COSV62093525; called by muse, varscan2
- DZIP1 | c.2377G>A p.D793N (on ENST00000347108; = p.D774N on NM_014934.5) | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1027329288; called by muse, mutect2, varscan2
- E2F1 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 25/189 reads (13%) | catalogued as COSV99864447; called by muse, mutect2, varscan2
- EARS2 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV101492162; called by muse, mutect2, varscan2
- EHMT1 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs970059219; called by muse, mutect2, varscan2
- EPHA8 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1451737171; called by muse, mutect2
- EPHB6 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.301); catalogued as COSV101235980; called by muse, mutect2
- EXOC3L2 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.952); catalogued as rs759287672; called by muse, mutect2, varscan2
- EXTL3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.695); catalogued as rs762001581, COSV55037255; called by muse, mutect2, varscan2
- FAM171A1 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs76394384; called by mutect2, varscan2
- FAM47B | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 13/188 reads (7%) | catalogued as COSV61452510, COSV61454357; called by muse, mutect2
- FANCI | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 78/622 reads (13%) | catalogued as COSV55528614; called by muse, mutect2, varscan2
- FAT2 | c.4903C>T p.Q1635* | Nonsense Mutation (SNP) | VAF 42/365 reads (12%) | catalogued as COSV55822321; called by muse, mutect2, varscan2
- FBN2 | c.4723C>A p.R1575S | Missense Mutation (SNP) | VAF 163/907 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV52528022; called by muse, mutect2, varscan2
- FBXL19 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV57942078; called by muse, mutect2, varscan2
- FBXO43 | c.1448C>G p.A483G | Missense Mutation (SNP) | VAF 66/424 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1027188595; called by muse, mutect2, varscan2
- FGA | c.2145C>A p.H715Q | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57397724; called by muse, mutect2
- FGG | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 28/740 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV60194635; called by muse, mutect2
- FIZ1 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1385047157, COSV104380363; called by muse, mutect2, varscan2
- FLG | c.10526C>T p.A3509V | Missense Mutation (SNP) | VAF 93/500 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1248200226; called by muse, mutect2, varscan2
- FLG | c.5221G>T p.G1741W | Missense Mutation (SNP) | VAF 66/527 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100911289, COSV64236110; called by muse, mutect2, varscan2
- FLG | c.1279G>T p.G427* | Nonsense Mutation (SNP) | VAF 88/548 reads (16%) | catalogued as rs544327834; called by muse, mutect2, varscan2
- FLNB | c.5762G>C p.G1921A | Missense Mutation (SNP) | VAF 61/413 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99912540; called by muse, mutect2, varscan2
- FRMPD1 | c.1724C>A p.T575N | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.276); catalogued as rs1459264668; called by muse, mutect2, varscan2
- FSTL4 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531240; called by muse, mutect2, varscan2
- GFI1B | c.376A>G p.M126V | Missense Mutation (SNP) | VAF 49/361 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1274965157; called by muse, mutect2, varscan2
- GLA | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 63/537 reads (12%) | catalogued as rs869312283, COSV99516408; called by muse, mutect2, varscan2
- GLB1L3 | c.1508G>T p.R503L | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV68393574, COSV68393584; called by muse, mutect2, varscan2
- GLI3 | c.3895G>T p.V1299L | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as CD107048; called by muse, mutect2, varscan2
- GPALPP1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100689116; called by muse, mutect2, varscan2
- GPR15 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 73/507 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52520641, COSV52521171, COSV99423711; called by muse, mutect2, varscan2
- GPR158 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 75/629 reads (12%) | catalogued as COSV100892719; called by muse, mutect2, varscan2
- GPR50 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV54438356, COSV54438852; called by muse, mutect2
- GRAMD4 | c.1139C>G p.P380R | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs764265042, COSV100730636, COSV63031782, COSV63033070; called by muse, mutect2, varscan2
- GRIN3A | c.2341C>T p.H781Y | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV62451458; called by muse, mutect2, varscan2
- GRM2 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99622750; called by muse, mutect2, varscan2
- GSPT2 | c.821C>A p.A274D | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61215032; called by muse, mutect2, varscan2
- GSX2 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 62/488 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58842889; called by muse, mutect2, varscan2
- GUCY2F | c.1555del p.H519Tfs*12 | Frame Shift Del (DEL) | VAF 31/234 reads (13%) | catalogued as COSV99484988; called by mutect2, pindel, varscan2
- HFE | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 47/835 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs111033558, CM990722; called by muse, mutect2
- HMCN1 | c.5596C>A p.P1866T | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775063304; called by muse, mutect2, varscan2
- HPGD | c.498G>A p.A166= | Splice Region (SNP) | VAF 74/504 reads (15%) | catalogued as rs200828629, COSV56663253, COSV99640324; called by muse, mutect2, varscan2
- HTR1A | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 30/272 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV60500543; called by muse, mutect2, varscan2
- HUWE1 | c.11354C>T p.A3785V | Missense Mutation (SNP) | VAF 61/480 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.236); catalogued as COSV53366993; called by muse, mutect2, varscan2
- IGHV2-5 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 97/647 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1555425627; called by muse, mutect2, varscan2
- IL13RA1 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 53/634 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65425020; called by muse, mutect2
- IL17RA | c.2229C>G p.D743E | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs768137463, COSV100082759; called by muse, mutect2, varscan2
- IL17RD | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 72/504 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99577729; called by muse, varscan2
- IL1RN | c.380G>T p.R127L (on ENST00000409930 / NM_173842.3; = p.R109L on NM_000577.5) | Missense Mutation (SNP) | VAF 90/463 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as rs780956028, COSV52081983; called by muse, mutect2, varscan2
- IL23R | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760637251; called by muse, mutect2, varscan2
- IL26 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs1303290770; called by muse, mutect2, varscan2
- INPP5D | c.1301C>T p.T434M (on ENST00000445964 / NM_001017915.3; = p.T433M on NM_005541.5) | Missense Mutation (SNP) | VAF 75/547 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455642398, COSV64039767; called by muse, mutect2, varscan2
- IZUMO2 | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV53231259; called by muse, mutect2, varscan2
- JAKMIP3 | c.1476C>T p.G492= | Splice Region (SNP) | VAF 12/126 reads (10%) | catalogued as rs760172819; called by muse, mutect2, varscan2
- KAT8 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462936834; called by mutect2, varscan2
- KDM5A | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 84/672 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101238690; called by muse, mutect2, varscan2
- KDR | c.1532del p.N511Tfs*4 | Frame Shift Del (DEL) | VAF 65/461 reads (14%) | catalogued as rs1312292981; called by mutect2, pindel, varscan2
- KERA | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 131/451 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs756854659, COSV99899419; called by muse, mutect2, varscan2
- KIAA1210 | c.1843G>T p.D615Y | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV68176430; called by muse, mutect2, varscan2
- KIF19 | c.1005C>G p.N335K | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV63430138; called by muse, mutect2
- KIF21A | c.2501G>T p.R834L (on ENST00000361418 / NM_001378440.1; = p.R821L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/745 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV62766947; called by muse, mutect2, varscan2
- KMT2C | c.2306C>T p.S769L | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs771146833, COSV51450334; called by muse, varscan2
- KRT73 | c.1243C>A p.R415S | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV59841087; called by muse, mutect2, varscan2
- KRTAP24-1 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); catalogued as COSV61089383; called by muse, mutect2, varscan2
- LAYN | c.463C>G p.H155D (on ENST00000375615 / NM_001258390.1; = p.H147D on NM_178834.5) | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763383905, COSV65104453; called by muse, mutect2, varscan2
- LCP2 | c.254+7G>A | Splice Region (SNP) | VAF 65/401 reads (16%) | catalogued as COSV99252514; called by muse, mutect2, varscan2
- LGI2 | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 41/340 reads (12%) | catalogued as COSV66122402; called by muse, varscan2
- LHX2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV65318062; called by muse, mutect2, varscan2
- LLGL2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs533568617, COSV99389047; called by muse, mutect2
- LORICRIN | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | PolyPhen possibly damaging (0.785); catalogued as COSV64201498; called by muse, varscan2
- LRRC9 | c.4360T>C p.*1454Qext*1 | Nonstop Mutation (SNP) | VAF 46/316 reads (15%) | catalogued as rs551997975; called by muse, mutect2, varscan2
- MAGED1 | c.1726C>A p.R576S | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV58516094; called by muse, mutect2
- MASP2 | c.1814C>A p.P605Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99534043; called by muse, mutect2, varscan2
- MCTP2 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100537504; called by muse, varscan2
- MED15 | c.1294A>G p.M432V (on ENST00000263205 / NM_001003891.3; = p.M392V on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs748595037; called by muse, mutect2, varscan2
- MEIS2 | c.664G>A p.D222N (on ENST00000561208 / NM_170675.5; = p.D209N on NM_002399.3) | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as rs753490361, COSV54931769; called by muse, mutect2, varscan2
- MRGPRX3 | c.755A>T p.H252L | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.474); catalogued as rs1260319527; called by muse, mutect2, varscan2
- MROH6 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1186162614; called by muse, mutect2, varscan2
- MRPL21 | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62913775; called by muse, mutect2, varscan2
- MSLN | c.1612G>A p.A538T (on ENST00000382862 / NM_013404.4; = p.A530T on NM_005823.6) | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1006705365; called by muse, mutect2, varscan2
- MTCP1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 76/340 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV62900208; called by muse, mutect2, varscan2
- MTMR6 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 52/305 reads (17%) | catalogued as rs373972921, COSV67808996; called by muse, mutect2, varscan2
- MUC4 | c.6279C>A p.H2093Q | Missense Mutation (SNP) | VAF 56/1454 reads (4%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.234); catalogued as COSV62159341; called by muse, mutect2
- MYBPC2 | c.2807C>A p.P936H | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1414329572, COSV63101053; called by muse, mutect2, varscan2
- MYCN | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 127/776 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55258002, COSV55258567, COSV55261766; called by muse, mutect2, varscan2
- MYH4 | c.5341G>T p.A1781S | Missense Mutation (SNP) | VAF 88/653 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV55111968; called by muse, mutect2, varscan2
- MYH7B | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53418256; called by muse, mutect2, varscan2
- MYO18B | c.6743C>G p.A2248G | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV59153861; called by muse, mutect2, varscan2
- MYO7B | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 34/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768830460; called by muse, mutect2, varscan2
- MYT1L | c.2371C>A p.L791M | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as COSV67712020; called by muse, mutect2, varscan2
- NAA25 | c.2548G>A p.V850I | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55709422; called by muse, mutect2, varscan2
- NAV3 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99892000, COSV99894324; called by muse, mutect2, varscan2
- NCOA6 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770674512; called by muse, mutect2, varscan2
- NDST3 | c.2305G>T p.G769W | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56619072, COSV99630267; called by muse, mutect2
- NIBAN3 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV56310721; called by muse, mutect2, varscan2
- NLGN2 | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57208813; called by muse, mutect2, varscan2
- NRXN1 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV101277807; called by muse, varscan2
- NUP98 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1466518632; called by muse, varscan2
- OAS2 | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1466558381; called by muse, varscan2
- OR14K1 | c.825C>G p.F275L | Missense Mutation (SNP) | VAF 146/816 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.262); catalogued as rs768773116; called by muse, mutect2, varscan2
- OR2AK2 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as rs141137318; called by muse, mutect2, varscan2
- OR2H1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs777238942, COSV101009803; called by muse, mutect2
- OR2L8 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs1257084961, COSV61727333; called by muse, mutect2, varscan2
- OR2T2 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 85/1836 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100737621; called by muse, mutect2
- OR2T6 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV63216963; called by muse, varscan2
- OR4D11 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV57584595; called by muse, mutect2, varscan2
- OR4D5 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58307324; called by muse, mutect2, varscan2
- OR51C1P | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 61/404 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as rs540475066; called by muse, mutect2, varscan2
- OR52K2 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57834547; called by muse, mutect2, varscan2
- OR5F1 | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762828062, COSV99558860; called by muse, mutect2, varscan2
- PALB2 | c.2156C>G p.P719R | Missense Mutation (SNP) | VAF 100/691 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as rs1555460467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAQR9 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.042); catalogued as COSV61418151; called by muse, mutect2, varscan2
- PARD3B | c.3580G>T p.D1194Y (on ENST00000406610 / NM_001302769.2; = p.D1125Y on NM_057177.7) | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100593254; called by muse, mutect2, varscan2
- PCARE | c.1647C>A p.S549R | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59056895; called by muse, mutect2, varscan2
- PCCA | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 110/690 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV66196629; called by muse, mutect2, varscan2
- PCDH11X | c.3137C>A p.A1046E | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV53462856; called by muse, mutect2, varscan2
- PCDH15 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.347); catalogued as COSV57273115; called by muse, mutect2, varscan2
- PCDHA1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100974305; called by muse, mutect2, varscan2
- PCDHB14 | c.464A>T p.E155V | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53390414; called by muse, mutect2, varscan2
- PCDHB5 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV50665201; called by muse, mutect2, varscan2
- PCDHB9 | c.2220C>A p.S740R | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.092); catalogued as rs2910321; called by muse, mutect2
- PCDHGB4 | c.1085C>A p.T362K | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1392290138; called by muse, mutect2, varscan2
- PCDHGB4 | c.1906G>T p.V636F | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as COSV53949039; called by muse, mutect2, varscan2
- PDE4D | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.072); catalogued as COSV72350674; called by muse, mutect2, varscan2
- PDZD7 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100931574; called by muse, mutect2, varscan2
- PGAM4 | c.137G>C p.R46P | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782301078, COSV58457134; called by muse, mutect2, varscan2
- PGR | c.2387C>A p.S796* | Nonsense Mutation (SNP) | VAF 63/516 reads (12%) | catalogued as COSV54812258; called by muse, mutect2, varscan2
- PGR | c.1226C>A p.A409D | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as rs1274438915; called by muse, mutect2, varscan2
- PIK3R6 | c.1692G>T p.K564N | Missense Mutation (SNP) | VAF 141/466 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); catalogued as rs781638550; called by muse, mutect2, varscan2
- PKDCC | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs758488715, COSV54306656; called by muse, mutect2, varscan2
- PLA2G3 | c.997A>G p.M333V | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762780314, COSV53208137; called by muse, mutect2, varscan2
- PLXNA4 | c.3252+1G>A p.X1084_splice | Splice Site (SNP) | VAF 55/438 reads (13%) | catalogued as COSV100323931; called by muse, mutect2, varscan2
- POLD1 | c.2293G>T p.V765L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV101486816; called by muse, mutect2
- PPIG | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 51/252 reads (20%) | catalogued as COSV53643881; called by muse, mutect2, varscan2
- PPP1R16B | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100239865; called by muse, mutect2, varscan2
- PRAMEF2 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 32/537 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53579923; called by muse, mutect2
- PRDM9 | c.102C>G p.Y34* | Nonsense Mutation (SNP) | VAF 79/636 reads (12%) | catalogued as COSV57005990; called by muse, mutect2, varscan2
- PRG4 | c.2515C>A p.P839T | Missense Mutation (SNP) | VAF 78/577 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63356060; called by muse, mutect2, varscan2
- PRLR | c.1075del p.L359Ffs*39 | Frame Shift Del (DEL) | VAF 56/388 reads (14%) | catalogued as COSV51501449; called by mutect2, pindel, varscan2
- PSG2 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68884310; called by muse, mutect2, varscan2
- PYHIN1 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.101); catalogued as rs373957516; called by muse, mutect2, varscan2
- RAB3B | c.229-1G>T p.X77_splice | Splice Site (SNP) | VAF 8/142 reads (6%) | catalogued as COSV65434971; called by muse, mutect2
- RASAL2 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 22/216 reads (10%) | catalogued as COSV62723917; called by muse, mutect2, varscan2
- REPIN1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs11553624; called by muse, mutect2, varscan2
- RGPD3 | c.3190G>T p.G1064W | Missense Mutation (SNP) | VAF 103/812 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58741264; called by muse, mutect2, varscan2
- RGSL1 | c.1515C>A p.S505R | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54255811; called by muse, mutect2, varscan2
- RHBDF2 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV51686361; called by muse, mutect2, varscan2
- ROBO1 | c.2546G>A p.S849N | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV101458581; called by muse, mutect2, varscan2
- RPE65 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 72/695 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130733, CM1514184; called by muse, mutect2
- RPL15 | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57139840; called by muse, mutect2, varscan2
- RYR1 | c.8332G>T p.G2778* | Nonsense Mutation (SNP) | VAF 75/340 reads (22%) | catalogued as COSV62098045; called by muse, mutect2, varscan2
- SAMD9L | c.1777C>G p.L593V | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV59081889; called by muse, mutect2, varscan2
- SCAF11 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 66/553 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99874022; called by muse, mutect2, varscan2
- SCNN1B | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs765382334; called by muse, mutect2, varscan2
- SERPINI2 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99248094; called by muse, mutect2, varscan2
- SH3BP5L | c.668G>C p.R223P | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63539046; called by muse, mutect2, varscan2
- SH3TC1 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV55282930; called by muse, mutect2, varscan2
- SHROOM2 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773234401, COSV101098891; called by mutect2, varscan2
- SHROOM2 | c.4523G>A p.R1508H | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs760200009, COSV66608522; called by muse, mutect2, varscan2
- SHROOM2 | c.4769G>T p.R1590L | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101099017; called by muse, mutect2, varscan2
- SLAIN2 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 51/335 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs778310300, COSV51906120; called by muse, mutect2, varscan2
- SLC12A5 | c.1182G>T p.R394S (on ENST00000454036 / NM_001134771.2; = p.R371S on NM_020708.5) | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV54795454; called by muse, mutect2, varscan2
- SLC14A1 | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 102/767 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs141539101; called by muse, mutect2, varscan2
- SLC16A9 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV68098875; called by muse, mutect2, varscan2
- SLC38A6 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs567384048; called by muse, mutect2, varscan2
- SPATA16 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 93/524 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459343937, COSV63532145, COSV63532636; called by muse, mutect2, varscan2
- SPEF2 | c.3080T>C p.L1027S | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774735931; called by muse, mutect2, varscan2
- SPHKAP | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 49/471 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100763559; called by muse, mutect2, varscan2
- SPRR2F | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 23/207 reads (11%) | PolyPhen benign (0); catalogued as COSV64206732; called by muse, mutect2, varscan2
- STAT6 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV55672283; called by muse, mutect2, varscan2
- STRN3 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770591764, COSV62582176; called by muse, mutect2, varscan2
- SVEP1 | c.3301del p.V1101* | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as COSV57041497; called by mutect2, pindel, varscan2
- TAAR8 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 58/503 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51586250; called by muse, mutect2, varscan2
- TAS2R5 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 60/419 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV56095669; called by muse, mutect2, varscan2
- TAS2R60 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 84/646 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.216); catalogued as rs764254335; called by muse, mutect2, varscan2
- TBRG1 | c.1098G>T p.L366F | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs530121051, COSV52515768; called by muse, varscan2
- TEK | c.2059G>T p.V687L | Missense Mutation (SNP) | VAF 61/606 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as COSV66231569; called by muse, mutect2, varscan2
- TENM1 | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.069); catalogued as COSV64431137, COSV64439923; called by muse, mutect2, varscan2
- TEX13A | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as COSV61163456, COSV99049192; called by muse, mutect2
- THSD7B | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 89/725 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV55667968; called by muse, mutect2, varscan2
- TKTL2 | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.145); catalogued as COSV54920931; called by muse, mutect2, varscan2
- TLN2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60891869, COSV60896194; called by muse, mutect2, varscan2
- TMEM47 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs1473757141; called by muse, mutect2, varscan2
- TPO | c.1946C>A p.T649K | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61103614; called by muse, mutect2, varscan2
- TRANK1 | c.3799C>A p.R1267S | Missense Mutation (SNP) | VAF 75/467 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as rs766366207, COSV57151852, COSV57152176; called by muse, mutect2, varscan2
- TREM1 | c.475A>T p.T159S | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV55148661; called by muse, mutect2, varscan2
- TRHDE | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052400108, COSV53858310; called by muse, mutect2, varscan2
- TRIM36 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as COSV56692550, COSV99142320; called by muse, mutect2, varscan2
- TRIM49 | c.977G>T p.R326I | Missense Mutation (SNP) | VAF 40/382 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV61671868; called by muse, varscan2
- TRIM67 | c.2155G>A p.V719M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1316901643, COSV64158724; called by muse, mutect2, varscan2
- TRMT2B | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100105185; called by muse, mutect2
- TRPV5 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs544283001, COSV54683375; called by muse, mutect2, varscan2
- TRPV6 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV63892260; called by muse, mutect2, varscan2
- TSPAN16 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs779473677; called by muse, mutect2, varscan2
- TSPYL2 | c.1560C>A p.D520E | Missense Mutation (SNP) | VAF 76/658 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV100966350; called by muse, mutect2, varscan2
- TTC3 | c.4896G>C p.E1632D | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100695332; called by muse, mutect2, varscan2
- TUBGCP3 | c.533A>T p.Q178L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs779170471; called by muse, mutect2, varscan2
- UGT3A2 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56932411; called by muse, mutect2, varscan2
- URGCP | c.988G>T p.E330* (on ENST00000453200 / NM_001077663.3; = p.E321* on NM_017920.4) | Nonsense Mutation (SNP) | VAF 81/546 reads (15%) | catalogued as COSV56245257; called by muse, mutect2, varscan2
- USP48 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 77/454 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs757332967; called by muse, mutect2, varscan2
- VWC2L | c.390+6C>G | Splice Region (SNP) | VAF 44/232 reads (19%) | catalogued as rs772972126, COSV56974429; called by muse, mutect2, varscan2
- WARS1 | c.422+1G>T p.X141_splice | Splice Site (SNP) | VAF 26/159 reads (16%) | catalogued as rs1211258806; called by muse, mutect2, varscan2
- WDFY3 | c.6512G>T p.W2171L | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV55712154; called by muse, mutect2
- WDFY4 | c.2791C>G p.P931A | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV57423986; called by muse, mutect2, varscan2
- WDR49 | c.1027G>T p.G343W (on ENST00000308378 / NM_001366158.1; = p.G684W on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/469 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs376902900; called by muse, mutect2, varscan2
- WWC3 | c.2106G>T p.L702= | Splice Region (SNP) | VAF 15/80 reads (19%) | catalogued as COSV66506490; called by muse, varscan2
- ZBTB1 | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62439865; called by muse, mutect2, varscan2
- ZFX | c.2312C>A p.T771K | Missense Mutation (SNP) | VAF 76/614 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58447599; called by muse, mutect2, varscan2
- ZNF135 | c.359G>A p.G120D (on ENST00000313434 / NM_001289401.2; = p.G132D on NM_003436.4) | Missense Mutation (SNP) | VAF 81/410 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs1347949139; called by muse, varscan2
- ZNF277 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs1414233427; called by muse, mutect2, varscan2
- ZNF407 | c.3028G>T p.D1010Y | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV99996624; called by muse, mutect2, varscan2
- ZNF454 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.07); catalogued as COSV100195430; called by muse, mutect2, varscan2
- ZNF462 | c.3511G>T p.A1171S | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.067); catalogued as COSV52948224; called by muse, mutect2, varscan2
- ZNF845 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV72004214; called by muse, mutect2, varscan2
- ZNF98 | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV63338754; called by muse, mutect2, varscan2
- ZPBP | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99250242; called by muse, mutect2, varscan2
- ZXDA | c.1050C>A p.H350Q | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62388060; called by muse, mutect2, varscan2
- ZYX | c.970C>G p.R324G | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.2); catalogued as COSV59556557, COSV59557774; called by muse, mutect2, varscan2
- ABCA2 | c.1516-1G>C p.X506_splice (on ENST00000614293; = p.X476_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- ABCB1 | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 90/732 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.3958A>G p.I1320V | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ABCB4 | c.2756A>G p.Y919C | Missense Mutation (SNP) | VAF 70/549 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB5 | c.3589G>A p.A1197T (on ENST00000404938 / NM_001163941.2; = p.A752T on NM_178559.6) | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, varscan2
- ABCB6 | c.2412G>T p.E804D | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- ABCC10 | c.2752A>C p.S918R (on ENST00000372530 / NM_001198934.2; = p.S890R on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.172); called by muse, mutect2
- ABCC4 | c.1694T>A p.V565E | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- ABL1 | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- AC006059.2 | c.1952C>A p.T651N | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- AC013489.1 | c.1535A>T p.H512L | Missense Mutation (SNP) | VAF 57/463 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ACAD10 | c.1640G>T p.W547L | Missense Mutation (SNP) | VAF 117/407 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ACAD10 | c.1641G>T p.W547C | Missense Mutation (SNP) | VAF 115/406 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ACE | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACOT12 | c.1583G>A p.W528* | Nonsense Mutation (SNP) | VAF 37/319 reads (12%) | called by muse, mutect2, varscan2
- ACSBG2 | c.1701C>A p.S567R | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ACSM2A | c.347T>C p.V116A (on ENST00000219054; = p.V37A on NM_001308169.2) | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ACSM4 | c.580del p.Q194Kfs*31 | Frame Shift Del (DEL) | VAF 75/502 reads (15%) | called by mutect2, pindel, varscan2
- ACTL9 | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.303); called by muse, mutect2
- ADAMTS12 | c.568C>G p.H190D | Missense Mutation (SNP) | VAF 53/369 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, varscan2
- ADAMTS13 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ADAMTS4 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ADAP2 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ADARB2 | c.1357C>A p.L453M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- ADGB | c.4771C>G p.R1591G | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- ADGRE5 | c.897+8C>A | Splice Region (SNP) | VAF 23/145 reads (16%) | called by muse, mutect2, varscan2
- ADGRG7 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADH1A | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 61/419 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADK | c.57A>T p.Q19H | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADSL | c.415A>T p.I139F | Missense Mutation (SNP) | VAF 106/701 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- AGBL3 | c.2293C>A p.Q765K | Missense Mutation (SNP) | VAF 53/297 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- AGFG2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- AHNAK2 | c.9640G>T p.G3214C | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AHNAK2 | c.7942T>A p.F2648I | Missense Mutation (SNP) | VAF 49/320 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- AIFM3 | c.941T>A p.V314E | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AIM2 | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 110/575 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AKAP13 | c.5182del p.L1728Cfs*82 (on ENST00000394518 / NM_007200.5; = p.L1732Cfs*82 on NM_006738.6) | Frame Shift Del (DEL) | VAF 42/297 reads (14%) | called by mutect2, pindel, varscan2
- AKAP4 | c.1368T>A p.H456Q | Missense Mutation (SNP) | VAF 61/439 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 72/484 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ALKBH1 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by mutect2, varscan2
- ALPG | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- AMOT | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 85/670 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPH | c.750-1G>T p.X250_splice | Splice Site (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2
- ANKRD60 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AOPEP | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, varscan2
- AP2A2 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APCDD1 | c.1132A>C p.T378P | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- APCDD1 | c.1501C>A p.L501I | Missense Mutation (SNP) | VAF 45/299 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APCS | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ARHGAP30 | c.1888T>A p.S630T | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP31 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGAP31 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 88/576 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by mutect2, varscan2
- ARHGEF12 | c.348+1del | Frame Shift Del (DEL) | VAF 30/291 reads (10%) | called by mutect2, pindel, varscan2
- ARHGEF12 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 35/324 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ARHGEF4 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF9 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- ARID2 | c.2869G>T p.G957C | Missense Mutation (SNP) | VAF 69/539 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ARID3A | c.775del p.V259* | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- ARPP21 | c.2194del p.Q732Rfs*48 | Frame Shift Del (DEL) | VAF 22/210 reads (10%) | called by mutect2, pindel
- ASB17 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 57/492 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASPM | c.8188_8189insG p.T2730Sfs*21 | Frame Shift Ins (INS) | VAF 38/253 reads (15%) | called by pindel, varscan2
- ASPM | c.8183T>G p.V2728G | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, varscan2
- ASTL | c.1161G>A p.W387* | Nonsense Mutation (SNP) | VAF 47/325 reads (14%) | called by muse, mutect2, varscan2
- ASTN1 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ASTN2 | c.2495C>A p.P832H (on ENST00000313400 / NM_001365069.1; = p.P781H on NM_014010.5) | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATAD1 | c.316A>C p.T106P | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ATF2 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATG9A | c.2351G>T p.R784L | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ATIC | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 124/714 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by mutect2, varscan2
- ATP2B3 | c.815del p.G272Efs*5 | Frame Shift Del (DEL) | VAF 43/195 reads (22%) | called by mutect2, pindel, varscan2
- ATP7A | c.2627-1G>T p.X876_splice | Splice Site (SNP) | VAF 45/426 reads (11%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2960A>C p.H987P | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.39); called by muse, mutect2
- B3GAT2 | c.368G>T p.S123I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- BAG3 | c.719A>T p.Y240F | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCKDK | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- BEST3 | c.214T>A p.Y72N | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BET1 | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BHLHA15 | c.314T>A p.V105E | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIN2 | c.222G>C p.M74I | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- BPIFB6 | c.1122G>C p.Q374H | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- BRINP2 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BTBD18 | c.1956del p.K653Rfs*13 | Frame Shift Del (DEL) | VAF 38/226 reads (17%) | called by mutect2, pindel*, varscan2
- C12orf29 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- C19orf25 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- C19orf38 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf87 | c.1192+1G>T p.X398_splice | Splice Site (SNP) | VAF 64/307 reads (21%) | called by muse, mutect2, varscan2
- C3 | c.3449C>A p.S1150* | Nonsense Mutation (SNP) | VAF 123/511 reads (24%) | called by muse, mutect2, varscan2
- CA5B | c.619-1G>T p.X207_splice | Splice Site (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.2548G>T p.A850S (on ENST00000479441 / NM_001174051.3; = p.A843S on NM_006030.4) | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- CADPS2 | c.2305G>T p.G769* | Nonsense Mutation (SNP) | VAF 20/192 reads (10%) | called by muse, mutect2
- CALY | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CAPN3 | c.912_913del p.D305Pfs*6 | Frame Shift Del (DEL) | VAF 48/469 reads (10%) | called by pindel, varscan2
- CARF | c.1494+1G>T p.X498_splice | Splice Site (SNP) | VAF 48/394 reads (12%) | called by muse, mutect2, varscan2
- CASP8 | c.1276T>G p.C426G (on ENST00000432109 / NM_033355.3; = p.C443G on NM_001228.4) | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CATSPER2 | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBLN2 | c.470C>G p.T157S | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CCAR1 | c.2248A>T p.S750C | Missense Mutation (SNP) | VAF 69/372 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CCDC105 | c.678C>A p.T226= | Splice Region (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- CCDC134 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CCDC33 | c.27G>C p.W9C | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC85A | c.1201G>T p.G401W | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- CCHCR1 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- CD248 | c.1485del p.Y496Tfs*21 | Frame Shift Del (DEL) | VAF 60/386 reads (16%) | called by mutect2, pindel, varscan2
- CD6 | c.1085-2A>T p.X362_splice | Splice Site (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- CD93 | c.1653C>A p.H551Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, varscan2
- CDC14A | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 103/944 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDH13 | c.1980G>T p.M660I | Missense Mutation (SNP) | VAF 72/688 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH18 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 83/708 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH22 | c.2225C>A p.P742Q | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CDH23 | c.3760G>T p.G1254W | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDH9 | c.1167G>T p.L389F | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CDK5RAP2 | c.2590C>G p.P864A | Missense Mutation (SNP) | VAF 89/859 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDON | c.2055G>T p.Q685H | Missense Mutation (SNP) | VAF 106/617 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CDR2L | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEL | c.1751_1752del p.P584Rfs*6 (on ENST00000673714; = p.P581Rfs*6 on NM_001807.6) | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | called by pindel, varscan2
- CEP152 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 55/503 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- CEP152 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 77/449 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CFAP251 | c.2200T>A p.L734I | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CHD3 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 101/361 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD6 | c.7717C>T p.P2573S | Missense Mutation (SNP) | VAF 55/413 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CKAP2 | c.1369G>T p.A457S (on ENST00000378037 / NM_001098525.2; = p.A456S on NM_018204.5) | Missense Mutation (SNP) | VAF 43/363 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CKMT1A | c.1252T>C p.*418Qext*6 | Nonstop Mutation (SNP) | VAF 50/293 reads (17%) | called by muse, mutect2, varscan2
- CLCNKB | c.1686G>T p.M562I | Missense Mutation (SNP) | VAF 77/359 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CLDN18 | c.721_722del p.Y241Rfs*24 | Frame Shift Del (DEL) | VAF 35/321 reads (11%) | called by pindel, varscan2
- CLTC | c.4224A>G p.I1408M | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- CLTCL1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2
- COL12A1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- COL3A1 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by mutect2, varscan2
- COL6A1 | c.1992G>T p.Q664H | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- COL6A1 | c.2665G>T p.A889S | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2
- COL6A3 | c.1285T>A p.L429M | Missense Mutation (SNP) | VAF 88/636 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CPNE7 | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPS1 | c.1546T>C p.C516R | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CR1 | c.3481G>T p.V1161F | Missense Mutation (SNP) | VAF 70/733 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CRB2 | c.2206G>T p.D736Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CREG2 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRISP2 | c.606C>T p.T202= | Splice Region (SNP) | VAF 15/91 reads (16%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CTRC | c.467A>T p.Y156F | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- CWF19L2 | c.1274G>T p.R425I | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, varscan2
- CWH43 | c.1632T>G p.F544L | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CXXC1 | c.1555T>C p.Y519H | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CYLD | c.1786G>A p.G596S | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP27B1 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CYP46A1 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DAPK3 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCDC1 | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- DDX1 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DEFA5 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- DES | c.1156C>A p.R386S | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DIP2B | c.3456G>T p.M1152I | Missense Mutation (SNP) | VAF 62/532 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, varscan2
- DISP2 | c.3142C>T p.R1048C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DISP3 | c.3446A>T p.Q1149L | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DKC1 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 74/887 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- DNAH11 | c.6521G>T p.G2174V | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH7 | c.8834C>A p.S2945* | Nonsense Mutation (SNP) | VAF 33/283 reads (12%) | called by muse, mutect2, varscan2
- DNAH7 | c.8554C>A p.L2852I | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- DNAH7 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- DNASE1L1 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DSEL | c.3189T>A p.N1063K | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DTX2 | c.168dup p.G57Wfs*22 | Frame Shift Ins (INS) | VAF 27/194 reads (14%) | called by mutect2, pindel, varscan2
- EBF2 | c.422A>T p.E141V | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EBF4 | c.220G>A p.A74T (on ENST00000609451; = p.A70T on NM_001110514.1) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- EBLN1 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 64/394 reads (16%) | called by muse, mutect2, varscan2
- EDA2R | c.780A>T p.Q260H | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFL1 | c.2444G>C p.R815T | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EFL1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- EHHADH | c.1666A>T p.R556W | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ELAVL4 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ELF5 | c.439G>T p.A147S (on ENST00000312319 / NM_198381.2; = p.A137S on NM_001422.4) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.027); called by muse, varscan2
- EN1 | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENTPD5 | c.1242G>T p.L414F | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ERC2 | c.2071A>G p.I691V | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRA | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 3/59 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2
- ESS2 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT2 | c.2205A>T p.R735S (on ENST00000613624; = p.R659S on NM_020728.3) | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.557); called by muse, mutect2
- EYA4 | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FADS2 | c.718G>T p.V240F | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM126A | c.744-1G>T p.X248_splice | Splice Site (SNP) | VAF 60/481 reads (12%) | called by muse, mutect2, varscan2
- FAM205A | c.1076C>G p.T359S | Missense Mutation (SNP) | VAF 85/576 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FAM20C | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.146); called by muse, mutect2
- FAM47A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM71B | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM71D | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 77/557 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM83E | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FANCM | c.2355A>T p.L785F | Missense Mutation (SNP) | VAF 51/388 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT2 | c.8607G>T p.Q2869H | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- FDXR | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 45/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FER1L6 | c.2762C>T p.P921L | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGA | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FGR | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- FIGNL1 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- FLNA | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- FLT3 | c.2582T>A p.F861Y | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- FLT3 | c.2530G>T p.V844F | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- FMNL2 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 85/654 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FNDC1 | c.4666G>T p.E1556* | Nonsense Mutation (SNP) | VAF 32/324 reads (10%) | called by muse, mutect2, varscan2
- FOXC1 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | called by muse, varscan2
- FOXD3 | c.1416A>T p.Q472H | Missense Mutation (SNP) | VAF 51/298 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FOXL2NB | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3875C>A p.P1292H | Missense Mutation (SNP) | VAF 53/340 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- FRY | c.2648G>T p.R883L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSCB | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- FSIP2 | c.2561A>G p.Q854R | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- GABRA2 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 88/581 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GABRA5 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 62/457 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- GABRA6 | c.867T>A p.S289R | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRE | c.1203T>G p.H401Q | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GALNT14 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2
- GALNT8 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 111/704 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GALNTL6 | c.1050G>T p.M350I | Missense Mutation (SNP) | VAF 13/364 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- GAS2L2 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- GCN1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- GFPT2 | c.340+1G>T p.X114_splice | Splice Site (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- GIGYF2 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- GIMAP8 | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 77/583 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GK2 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- GLG1 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 77/510 reads (15%) | called by muse, mutect2, varscan2
- GLP1R | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GLRB | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- GNB1 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 38/357 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA3 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA4 | c.3078dup p.E1027Rfs*8 | Frame Shift Ins (INS) | VAF 23/201 reads (11%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- GOLT1B | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 49/371 reads (13%) | called by muse, mutect2, varscan2
- GP5 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- GPR158 | c.2412G>C p.E804D | Missense Mutation (SNP) | VAF 71/622 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPR174 | c.250T>G p.W84G | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR45 | c.1112C>A p.A371E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- GPSM2 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 85/617 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRID2IP | c.2432C>A p.P811H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GRID2IP | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GRIK4 | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRM8 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- GSX1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- GTSE1 | c.1795T>A p.S599T | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GUCY2F | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- H4C3 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2
- HERC2 | c.11848G>T p.G3950C | Missense Mutation (SNP) | VAF 56/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HEXIM2 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- HHIPL1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- HHIPL2 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- HIF1A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 71/535 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HJV | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 67/434 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- HK1 | c.2521G>T p.V841F | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- HNRNPU | c.1685C>T p.P562L (on ENST00000283179; = p.P624L on NM_004501.3) | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HNRNPU | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HOMER1 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD4 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HRC | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HUWE1 | c.11567T>A p.L3856Q | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HUWE1 | c.9733C>G p.L3245V | Missense Mutation (SNP) | VAF 94/642 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYDIN | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDUA | c.903C>A p.D301E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFI16 | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IGF2R | c.6357G>T p.W2119C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGFBP1 | c.682T>C p.C228R | Missense Mutation (SNP) | VAF 36/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGFBP1 | c.683G>C p.C228S | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGKV2-30 | c.113del p.P38Rfs*21 | Frame Shift Del (DEL) | VAF 24/192 reads (13%) | called by mutect2, varscan2
- IGSF22 | c.835T>A p.Y279N | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- IGSF3 | c.3178C>T p.P1060S (on ENST00000369486 / NM_001007237.3; = p.P1080S on NM_001542.4) | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGSF9B | c.4120C>A p.Q1374K | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- IL12RB2 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- IL13RA1 | c.1010-1G>T p.X337_splice | Splice Site (SNP) | VAF 52/628 reads (8%) | called by muse, mutect2
- IL1RAPL1 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- IL22RA2 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 56/365 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IL36B | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- IMPA1 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 74/469 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- IMPG2 | c.1585G>C p.D529H | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- INCENP | c.1216A>T p.T406S | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.202); called by muse, mutect2
- INKA1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- INTS2 | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- IPO11 | c.1799G>C p.G600A | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IQUB | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRF7 | c.1199C>T p.A400V (on ENST00000397566; = p.A387V on NM_001572.5) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ITGA8 | c.1687C>A p.Q563K | Missense Mutation (SNP) | VAF 74/423 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- JADE3 | c.1453C>A p.L485M | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH4 | c.482C>G p.T161S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- JRKL | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 60/389 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- KCNB1 | c.2576G>T p.*859Lext*29 | Nonstop Mutation (SNP) | VAF 7/70 reads (10%) | called by muse, varscan2
- KCNC4 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KCNE5 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 60/400 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNH1 | c.464C>A p.T155K | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2
- KCNQ2 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- KCNQ5 | c.1327G>T p.G443C | Missense Mutation (SNP) | VAF 85/651 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNS3 | c.102del p.R35Gfs*46 | Frame Shift Del (DEL) | VAF 52/464 reads (11%) | called by pindel, varscan2
- KCNU1 | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNU1 | c.2725C>G p.L909V | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNV1 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KDM7A | c.1269dup p.P424Afs*27 | Frame Shift Ins (INS) | VAF 24/242 reads (10%) | called by pindel, varscan2
- KIF11 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- KIF13A | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF16B | c.3895G>T p.E1299* | Nonsense Mutation (SNP) | VAF 57/468 reads (12%) | called by muse, mutect2, varscan2
- KIF26B | c.4549C>A p.L1517M | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KIFC1 | c.1885G>C p.G629R | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- KLHL13 | c.178T>G p.S60A | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL34 | c.1397A>T p.H466L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL4 | c.2073T>A p.D691E | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KNDC1 | c.1092G>C p.W364C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- KRT16 | c.532-1G>T p.X178_splice | Splice Site (SNP) | VAF 48/420 reads (11%) | called by muse, mutect2, varscan2
- KRT6B | c.902T>A p.L301* | Nonsense Mutation (SNP) | VAF 123/941 reads (13%) | called by muse, mutect2, varscan2
- KRTAP4-16 | c.25A>C p.S9R | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated, low confidence (0.15); called by muse, mutect2, varscan2
- LAMA1 | c.1491_1492insT p.R498Sfs*13 | Frame Shift Ins (INS) | VAF 87/845 reads (10%) | called by mutect2, pindel, varscan2
- LAMP2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 65/555 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- LARP1 | c.2279C>A p.P760H (on ENST00000518297 / NM_033551.3; = p.P683H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- LCA5 | c.1979G>T p.S660I | Missense Mutation (SNP) | VAF 61/546 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by mutect2, varscan2
- LCMT1 | c.551A>T p.K184I | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, varscan2
- LCMT1 | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, varscan2
- LEXM | c.1023G>C p.K341N | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- LILRB1 | c.856G>T p.A286S (on ENST00000427581; = p.A250S on NM_006669.6) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- LINS1 | c.675A>T p.E225D | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LMAN1 | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- LONRF3 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPA | c.2689T>A p.Y897N | Missense Mutation (SNP) | VAF 131/1005 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- LPCAT2 | c.1092G>T p.L364F | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LRP1B | c.2741dup p.N914Kfs*2 | Frame Shift Ins (INS) | VAF 59/452 reads (13%) | called by mutect2, pindel, varscan2
- LRP1B | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRC4B | c.914G>C p.R305P | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRRN3 | c.641T>A p.L214H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM4 | c.768del p.H256Qfs*27 | Frame Shift Del (DEL) | VAF 41/342 reads (12%) | called by mutect2, pindel, varscan2
- LYPD8 | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 108/541 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAD1L1 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAML2 | c.1417G>T p.G473C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MAN2A2 | c.3251G>T p.G1084V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MAP7D3 | c.2407A>G p.K803E | Missense Mutation (SNP) | VAF 111/687 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- MAST1 | c.4189G>C p.E1397Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MATN3 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 76/555 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- MCF2L2 | c.2741G>T p.G914V | Missense Mutation (SNP) | VAF 58/450 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MCPH1 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MDGA2 | c.2839T>A p.W947R (on ENST00000399232 / NM_001113498.2; = p.W649R on NM_182830.4) | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDGA2 | c.1639T>A p.S547T (on ENST00000399232 / NM_001113498.2; = p.S249T on NM_182830.4) | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.247); called by muse, varscan2
- MDH1B | c.1046T>A p.F349Y | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.017); called by muse, varscan2
- MDH1B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MDN1 | c.4371G>C p.Q1457H | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.044); called by muse, mutect2
- MEOX2 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METRN | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MGAM2 | c.2941G>T p.A981S | Missense Mutation (SNP) | VAF 84/500 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MGAT5B | c.924dup p.G309Rfs*35 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- MKRN3 | c.1036A>T p.R346W | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MMP3 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); called by muse, mutect2
- MMP3 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2
- MMP9 | c.1114T>C p.W372R | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMRN1 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 40/214 reads (19%) | called by muse, mutect2, varscan2
- MOG | c.207C>A p.Y69* | Nonsense Mutation (SNP) | VAF 32/228 reads (14%) | called by muse, mutect2, varscan2
- MOV10 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 75/599 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MPPED1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 32/368 reads (9%) | called by muse, mutect2
- MS4A2 | c.308G>C p.W103S | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTMR8 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- MTOR | c.703A>C p.R235= | Splice Region (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- MUC13 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- MUC17 | c.5932C>A p.P1978T | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.4315T>C p.S1439P | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.15); called by muse, mutect2, varscan2
- MXRA5 | c.7995del p.Q2666Rfs*61 | Frame Shift Del (DEL) | VAF 24/195 reads (12%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.2672A>G p.Y891C (on ENST00000357337; = p.Y929C on NM_015057.5) | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH11 | c.2639A>T p.Q880L | Missense Mutation (SNP) | VAF 75/676 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.4947G>T p.L1649F | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO16 | c.4204C>G p.P1402A | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYOM1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 56/377 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA16 | c.2150A>T p.K717I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NAAA | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.288); called by muse, mutect2
- NALCN | c.3691-1G>T p.X1231_splice | Splice Site (SNP) | VAF 32/279 reads (11%) | called by muse, mutect2, varscan2
- NAT10 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- NAV3 | c.4198C>T p.L1400F | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NECAB2 | c.925T>A p.Y309N | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECTIN3 | c.397A>T p.I133F | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELL1 | c.2308A>T p.S770C | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NFAT5 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NFAT5 | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 46/332 reads (14%) | called by muse, varscan2
- NGLY1 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NHLH1 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NIBAN1 | c.2454G>C p.E818D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKAIN2 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- NKD2 | c.705C>A p.Y235* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- NLGN1 | c.835A>T p.N279Y | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NLRP14 | c.1271T>A p.L424Q | Missense Mutation (SNP) | VAF 154/947 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NMT2 | c.259C>G p.P87A | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, varscan2
- NPAT | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- NPIPB2 | c.556G>A p.G186R (on ENST00000399147; = p.G46R on NM_001355514.1) | Missense Mutation (SNP) | VAF 75/684 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPR1 | c.1247A>G p.E416G | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR4A2 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 89/517 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NRK | c.2866del p.D956Ifs*25 | Frame Shift Del (DEL) | VAF 35/269 reads (13%) | called by mutect2, pindel, varscan2
- NSD3 | c.4007G>T p.C1336F | Missense Mutation (SNP) | VAF 65/590 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NTNG1 | c.1430G>A p.G477E (on ENST00000370068 / NM_001113226.3; = p.G376E on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- NTRK2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 79/596 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NUGGC | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- NUP85 | c.732+1G>T p.X244_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- NXNL2 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 25/174 reads (14%) | called by muse, mutect2, varscan2
- OGA | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR10W1 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1C1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, varscan2
- OR2C3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, varscan2
- OR2G2 | c.732C>A p.C244* | Nonsense Mutation (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- OR2T34 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- OR4Q3 | c.374C>G p.T125R | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR52A5 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52R1 | c.693del p.L231Ffs*55 | Frame Shift Del (DEL) | VAF 52/393 reads (13%) | called by pindel, varscan2
- OR5K3 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR7C2 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8B2 | c.733G>T p.V245F | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); called by muse, mutect2
- OR8D2 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2
- OR8G1 | c.814A>T p.K272* | Nonsense Mutation (SNP) | VAF 34/400 reads (9%) | called by muse, mutect2
- ORC5 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- OSBPL7 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OTUD7B | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- P2RY4 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PABPC5 | c.361del p.A121Pfs*45 | Frame Shift Del (DEL) | VAF 62/566 reads (11%) | called by mutect2, pindel, varscan2
- PACS2 | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- PAGE5 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK5 | c.1743G>T p.R581= | Splice Region (SNP) | VAF 28/168 reads (17%) | called by muse, mutect2
- PAPPA | c.4487A>C p.Y1496S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- PARPBP | c.612A>T p.E204D | Missense Mutation (SNP) | VAF 73/568 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PBDC1 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH11X | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 80/676 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PCDH15 | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDH8 | c.945G>T p.E315D | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA1 | c.770dup p.N257Kfs*12 | Frame Shift Ins (INS) | VAF 49/322 reads (15%) | called by mutect2, pindel, varscan2
- PCDHB10 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 37/300 reads (12%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 22/588 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, mutect2
- PCDHB5 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 111/749 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB9 | c.2222G>C p.G741A | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2
- PCDHGC5 | c.1308A>C p.K436N | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCLO | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 45/395 reads (11%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE1A | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 78/478 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PDE3B | c.2275G>T p.G759C | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA2 | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PEX1 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 90/683 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PGBD5 | c.884G>T p.G295V (on ENST00000525115; = p.G364V on NM_001258311.2) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKA1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PHKA2 | c.1921G>T p.D641Y | Missense Mutation (SNP) | VAF 83/574 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, varscan2
- PHKG2 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHOX2B | c.489_497del p.A165_A167del | In Frame Del (DEL) | VAF 34/214 reads (16%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PKD1L1 | c.2950A>T p.T984S | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PKHD1 | c.10703T>A p.M3568K | Missense Mutation (SNP) | VAF 79/565 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLA2G5 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PLEKHD1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXDC1 | c.1228C>A p.Q410K | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.025); called by muse, mutect2
- PLXDC1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PLXNA2 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNPT1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PODN | c.1532T>A p.L511Q (on ENST00000395871; = p.L463Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- POLRMT | c.2713G>C p.V905L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POM121L2 | c.3067G>T p.E1023* | Nonsense Mutation (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2
- PORCN | c.555G>T p.L185= | Splice Region (SNP) | VAF 39/370 reads (11%) | called by muse, mutect2, varscan2
- POTEF | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.176); called by muse, mutect2
- PPEF1 | c.1502-1G>A p.X501_splice | Splice Site (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- PPP1R16B | c.467+1G>T p.X156_splice | Splice Site (SNP) | VAF 18/130 reads (14%) | called by muse, mutect2, varscan2
- PPP4R3C | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
679 further variants in this file (217 protein-altering or splice-affecting, 270 silent, 192 other) are not listed here.
